Somatic mutation profile of tumor specimen HTMCP-03-06-02404-01A (aliquot HTMCP-03-06-02404-01A-01D-10409) from CGCI case HTMCP-03-06-02404, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB2; Tumor grade: G1; Age at diagnosis: 33.8 years (12,352 days).
Specimen HTMCP-03-06-02404-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c15c48f3-72c0-40cc-ae68-e89e7580f4d1.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02404-10A (Blood Derived Normal), aliquot HTMCP-03-06-02404-10A-01D-10409; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4205829c-8dd9-46ab-b5c2-cf536f600e77

The open-access MAF lists 18 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 10, Silent 3, Frame Shift Ins 2, Splice Site 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4666dup p.T1556Nfs*3 | Frame Shift Ins (INS) | VAF 49/108 reads (45%) | catalogued as rs587783031, COSV57351096; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- ANKRD30A | c.3731A>G p.Y1244C (on ENST00000611781; = p.Y1188C on NM_052997.2) | Missense Mutation (SNP) | VAF 72/231 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.623); catalogued as rs1415471422; called by muse, mutect2, varscan2
- CADPS | c.3700G>A p.V1234M | Missense Mutation (SNP) | VAF 47/96 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV51866938; called by muse, mutect2, varscan2
- COL12A1 | c.4859C>A p.S1620Y | Missense Mutation (SNP) | VAF 45/149 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.098); catalogued as rs1315847355; called by muse, mutect2, varscan2
- MDN1 | c.13738G>A p.E4580K | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.67); catalogued as rs1266681737, COSV101020742; called by muse, mutect2, varscan2
- PCDHGB2 | c.2141G>A p.R714H | Missense Mutation (SNP) | VAF 61/95 reads (64%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as COSV99528897; called by muse, mutect2, varscan2
- RALGAPB | c.2731G>A p.G911S | Missense Mutation (SNP) | VAF 44/163 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as rs762668223; called by muse, mutect2, varscan2
- RBMXL1 | c.554G>A p.R185H | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.024); catalogued as rs753907563, COSV53101352; called by muse, mutect2, varscan2
- SMAD4 | c.431C>G p.S144* | Nonsense Mutation (SNP) | VAF 15/33 reads (45%) | catalogued as COSV61685296, COSV61696805; called by muse, mutect2, varscan2
- ELF3 | c.630dup p.D211Rfs*6 | Frame Shift Ins (INS) | VAF 19/30 reads (63%) | called by mutect2, pindel, varscan2
- ESPL1 | c.5446G>T p.A1816S | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2
- FAT3 | c.395C>T p.S132F | Missense Mutation (SNP) | VAF 64/181 reads (35%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDHAC1 | c.2540G>A p.G847E | Missense Mutation (SNP) | VAF 45/81 reads (56%) | SIFT tolerated (0.46); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- PTEN | c.13_23del p.I5Rfs*2 | Frame Shift Del (DEL) | VAF 21/48 reads (44%) | called by mutect2, pindel, varscan2
- PTPRC | c.2065+3_2065+6del p.X689_splice | Splice Site (DEL) | VAF 23/64 reads (36%) | called by mutect2, pindel, varscan2
- GOLGA1 | c.1710G>A p.L570= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV100764443; called by muse, mutect2, varscan2
- PCK1 | c.1398G>A p.A466= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as rs777300781; called by muse, varscan2
- SPEN | c.1842C>T p.A614= | Silent (SNP) | VAF 36/114 reads (32%) | catalogued as rs761461973; called by muse, mutect2, varscan2
